Somatic mutation profile of tumor specimen MMRF_2704_1_BM_CD138pos (aliquot MMRF_2704_1_BM_CD138pos_T1_KHS5U_L14434) from MMRF case MMRF_2704, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.7 years (21,451 days).
Specimen MMRF_2704_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 476ff564-41fe-4933-92fc-89c256d1e003.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2704_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2704_1_PB_WBC_C2_KHS5U_L14435; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e39de90-8897-4ef7-85cf-66f3485e29cf

The open-access MAF lists 88 somatic variants for this specimen: 36 protein-altering or splice-affecting, 17 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, 3'UTR 18, Silent 17, Intron 10, 5'UTR 4, Nonsense Mutation 4, 3'Flank 2, Splice Region 2, Frame Shift Ins 1, RNA 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 92/308 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, varscan2
- PANK3 | c.901A>T p.I301F | Missense Mutation (SNP) | VAF 4/25 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs77612793; called by mutect2, varscan2
- EPHB4 | c.2704C>T p.R902W | Missense Mutation (SNP) | VAF 85/243 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs200953030; called by muse, mutect2, varscan2
- FP565260.1 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 122/286 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1465323168; called by muse, varscan2
- GTPBP4 | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 116/304 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1009996576, COSV62551247; called by muse, mutect2, varscan2
- IGHJ5 | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 38/76 reads (50%) | PolyPhen probably damaging (0.986); catalogued as rs369944507; called by muse, varscan2
- LEMD3 | c.2494-5C>T | Splice Region (SNP) | VAF 13/41 reads (32%) | catalogued as COSV57652641; called by muse, mutect2, varscan2
- MAP4K4 | c.2725A>G p.T909A (on ENST00000347699 / NM_001242559.2; = p.T827A on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.616); catalogued as rs1181144744; called by muse, mutect2, varscan2
- MARCHF6 | c.2569G>A p.V857M | Missense Mutation (SNP) | VAF 87/253 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as rs200751600, COSV56879096; called by muse, mutect2, varscan2
- NOTCH4 | c.3449C>T p.T1150M | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs559963136, COSV100900811; called by muse, mutect2, varscan2
- OR2F1 | c.850A>G p.M284V | Missense Mutation (SNP) | VAF 105/241 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1299738055; called by muse, mutect2, varscan2
- PARD6B | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100859936; called by muse, mutect2, varscan2
- SMARCA1 | c.1819C>T p.R607* | Nonsense Mutation (SNP) | VAF 51/56 reads (91%) | catalogued as COSV64414082; called by muse, mutect2, varscan2
- TAF9 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 170/391 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs753648332; called by muse, mutect2, varscan2
- TFDP2 | c.799G>T p.A267S (on ENST00000489671 / NM_001178139.2; = p.A207S on NM_006286.5) | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.11); catalogued as rs1025563115; called by muse, varscan2
- TMPRSS9 | c.1556C>T p.T519I (on ENST00000648592; = p.T485I on NM_182973.2) | Missense Mutation (SNP) | VAF 69/212 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1480708352; called by muse, mutect2
- AGBL1 | c.1392A>C p.K464N | Missense Mutation (SNP) | VAF 127/331 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ARHGAP35 | c.4289A>G p.Q1430R | Missense Mutation (SNP) | VAF 131/570 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ASMTL | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CILP2 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FCRL2 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 95/200 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- H1-2 | c.342_343dup p.E115Gfs*53 | Frame Shift Ins (INS) | VAF 48/181 reads (27%) | called by pindel, varscan2
- IGLL5 | c.177_191del p.S59_L63del | In Frame Del (DEL) | VAF 10/42 reads (24%) | called by pindel, varscan2
- KLHL14 | c.622del p.Y208Tfs*54 | Frame Shift Del (DEL) | VAF 150/413 reads (36%) | called by mutect2, pindel, varscan2
- LLPH | c.304A>T p.R102* | Nonsense Mutation (SNP) | VAF 27/90 reads (30%) | called by muse, mutect2, varscan2
- MYH4 | c.135G>T p.E45D | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- NNT | c.3235A>C p.K1079Q | Missense Mutation (SNP) | VAF 106/508 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- NOS1 | c.850C>A p.Q284K | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPAT | c.224C>G p.S75* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | called by mutect2, varscan2
- SST | c.12C>A p.C4* | Nonsense Mutation (SNP) | VAF 54/142 reads (38%) | called by muse, varscan2
- SYCP3 | c.134-5T>A | Splice Region (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
- TFDP2 | c.800C>G p.A267G (on ENST00000489671 / NM_001178139.2; = p.A207G on NM_006286.5) | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.589); called by muse, varscan2
- TMEM63A | c.1373T>C p.L458P | Missense Mutation (SNP) | VAF 69/167 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TOE1 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 72/149 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WAPL | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 81/209 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- ZNF84 | c.367T>A p.L123I | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AMPH | c.51C>T p.L17= | Silent (SNP) | VAF 59/230 reads (26%) | catalogued as COSV57751507; called by muse, mutect2, varscan2
- C20orf85 | c.273C>T p.V91= | Silent (SNP) | VAF 61/166 reads (37%) | catalogued as COSV64519869; called by muse, mutect2, varscan2
- DNAH2 | c.919C>T p.L307= | Silent (SNP) | VAF 71/192 reads (37%) | catalogued as rs759729381; called by muse, mutect2, varscan2
- EGR3 | c.1035C>T p.S345= | Silent (SNP) | VAF 51/170 reads (30%) | called by muse, mutect2, varscan2
- FCN1 | c.480G>C p.R160= | Silent (SNP) | VAF 52/175 reads (30%) | called by muse, mutect2, varscan2
- FSBP | c.249A>T p.L83= | Silent (SNP) | VAF 53/142 reads (37%) | called by muse, mutect2, varscan2
- GSTP1 | c.96G>A p.E32= | Silent (SNP) | VAF 31/78 reads (40%) | called by muse, mutect2, varscan2
- HDX | c.642T>C p.S214= | Silent (SNP) | VAF 185/214 reads (86%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.102A>C p.G34= | Silent (SNP) | VAF 100/278 reads (36%) | catalogued as rs185369291; called by muse, varscan2
- MUC20 | c.1512C>T p.S504= | Silent (SNP) | VAF 214/906 reads (24%) | catalogued as rs769720088, COSV100290859; called by muse, mutect2, varscan2
- NCOA2 | c.3474C>T p.T1158= | Silent (SNP) | VAF 120/336 reads (36%) | called by muse, mutect2, varscan2
- OR8S1 | c.1056C>T p.R352= | Silent (SNP) | VAF 65/168 reads (39%) | catalogued as COSV59599608; called by muse, mutect2, varscan2
- PDZD4 | c.1704G>A p.S568= | Silent (SNP) | VAF 61/72 reads (85%) | called by muse, mutect2, varscan2
- PPP1R8 | c.531T>C p.I177= | Silent (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- PRKN | c.676T>C p.L226= | Silent (SNP) | VAF 90/185 reads (49%) | called by muse, mutect2, varscan2
- SH3TC2 | c.3090C>T p.S1030= | Silent (SNP) | VAF 108/242 reads (45%) | called by muse, mutect2, varscan2
- ZNF358 | c.714G>A p.P238= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as rs1358605087; called by muse, mutect2, varscan2
- AL132796.2 | n.1733C>T | RNA (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- ARHGAP10 | c.598-73T>C | Intron (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- ATF4 | c.-697G>A | 5'UTR (SNP) | VAF 45/123 reads (37%) | called by muse, mutect2, varscan2
- BIVM | c.*1258C>T | 3'UTR (SNP) | VAF 24/33 reads (73%) | called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81949753 C>T | 3'Flank (SNP) | VAF 27/62 reads (44%) | called by muse, mutect2, varscan2
- CCSER1 | c.*405T>G | 3'UTR (SNP) | VAF 22/37 reads (59%) | catalogued as COSV61463068; called by muse, mutect2, varscan2
- DCAF4L1 | c.*430C>T | 3'UTR (SNP) | VAF 41/87 reads (47%) | catalogued as rs183305755; called by muse, mutect2, varscan2
- DCAF8 | c.*419T>C | 3'UTR (SNP) | VAF 22/60 reads (37%) | catalogued as rs959516636; called by muse, mutect2, varscan2
- DLG4 | c.*640T>A | 3'UTR (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- DNAJC21 | c.*3223A>T | 3'UTR (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- EAF1 | c.*653C>T | 3'UTR (SNP) | VAF 65/190 reads (34%) | called by muse, mutect2, varscan2
- FOXJ2 | c.*152C>T | 3'UTR (SNP) | VAF 45/138 reads (33%) | called by muse, mutect2, varscan2
- IGKV4-1 | c.-62A>G | 5'UTR (SNP) | VAF 58/63 reads (92%) | called by muse, mutect2, varscan2
- LEPR | c.*4281T>C | 3'UTR (SNP) | VAF 56/144 reads (39%) | called by muse, mutect2, varscan2
- MAF | c.*1913C>T | 3'UTR (SNP) | VAF 22/78 reads (28%) | catalogued as rs1445272855; called by muse, mutect2, varscan2
- MRPL4 | c.57+10G>C | Intron (SNP) | VAF 50/153 reads (33%) | called by muse, mutect2, varscan2
- MYLK3 | c.*99T>C | 3'UTR (SNP) | VAF 229/545 reads (42%) | called by muse, mutect2, varscan2
- NOCT | c.-163G>A | 5'UTR (SNP) | VAF 122/263 reads (46%) | called by muse, mutect2, varscan2
- NRSN2 | c.*1020T>G | 3'UTR (SNP) | VAF 32/179 reads (18%) | catalogued as rs1185344404; called by muse, mutect2, varscan2
- OSR2 | c.-62C>T | 5'UTR (SNP) | VAF 112/426 reads (26%) | called by muse, mutect2, varscan2
- PCLO | c.14791+602C>T | Intron (SNP) | VAF 61/117 reads (52%) | called by muse, mutect2, varscan2
- PDE1C | c.1892-8901A>G | Intron (SNP) | VAF 42/97 reads (43%) | called by muse, mutect2, varscan2
- PITX2 | c.390+662T>G | Intron (SNP) | VAF 38/99 reads (38%) | called by muse, mutect2, varscan2
- PLIN2 | c.*370C>T | 3'UTR (SNP) | VAF 67/185 reads (36%) | called by muse, mutect2, varscan2
- PNPLA4 | c.*1506A>G | 3'UTR (SNP) | VAF 42/47 reads (89%) | called by muse, mutect2, varscan2
- PSMD6 | c.146-294C>T | Intron (SNP) | VAF 46/91 reads (51%) | called by muse, mutect2, varscan2
- SLC16A4 | c.1336+310T>A | Intron (SNP) | VAF 4/27 reads (15%) | catalogued as rs1455471385; called by muse, mutect2
- SLC6A2 | c.*471G>A | 3'UTR (SNP) | VAF 23/73 reads (32%) | called by muse, mutect2, varscan2
- SNX20 | chr16:50666964 A>C | 3'Flank (SNP) | VAF 59/167 reads (35%) | called by muse, varscan2
- TMSB4X | c.-17+49G>A | Intron (SNP) | VAF 77/92 reads (84%) | catalogued as rs1467208758; called by muse, mutect2, varscan2
- TMSB4X | c.-17+50G>A | Intron (SNP) | VAF 80/95 reads (84%) | catalogued as rs1172775460, COSV66081436; called by muse, mutect2, varscan2
- VPS13A | c.*2265T>G | 3'UTR (SNP) | VAF 66/147 reads (45%) | called by muse, mutect2, varscan2
- VPS37B | c.111+7510A>G | Intron (SNP) | VAF 29/85 reads (34%) | called by muse, mutect2, varscan2
- ZNF655 | c.*1346A>G | 3'UTR (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- ZNF860 | c.*464A>C | 3'UTR (SNP) | VAF 61/183 reads (33%) | called by muse, mutect2, varscan2
